Somatic mutation profile of tumor specimen MP2PRT-PARVSW-TMP1-A (aliquot MP2PRT-PARVSW-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PARVSW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,700 days).
Specimen MP2PRT-PARVSW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90022de0-b8f5-473e-ab12-a6614cd81613.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVSW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVSW-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dad79507-9152-49a2-8b83-58980f312d1c

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Splice Site 2, 5'Flank 1, Silent 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.1822-1G>C p.X608_splice (on ENST00000370717 / NM_001366005.1; = p.X595_splice on NM_012302.4) | Splice Site (SNP) | VAF 22/248 reads (9%) | catalogued as COSV99587298; called by muse, mutect2
- ARHGEF40 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 73/705 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs757284202; called by muse, mutect2, varscan2
- CCDC157 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 155/511 reads (30%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.556); catalogued as rs763055857; called by muse, mutect2, varscan2
- COL1A1 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 27/508 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.381); catalogued as rs754553279; called by muse, mutect2
- KRT1 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 156/533 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs200254456; called by muse, mutect2, varscan2
- MNS1 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 22/471 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1278264841, COSV99549350; called by muse, mutect2
- MUC5B | c.5969C>A p.T1990N | Missense Mutation (SNP) | VAF 52/1302 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as rs768433230; called by muse, mutect2
- TPST2 | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 155/581 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769303194; called by muse, mutect2, varscan2
- WDR4 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 118/429 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as rs779710658; called by muse, mutect2, varscan2
- ANKRD17 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 22/550 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2
- CCDC15 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 14/420 reads (3%) | called by muse, mutect2
- NECAB2 | c.947_962+2delinsGCCCC p.X316_splice | Splice Site (DEL) | VAF 86/412 reads (21%) | called by pindel, varscan2*
- QRICH2 | c.3506A>G p.Q1169R | Missense Mutation (SNP) | VAF 89/338 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- RASA3 | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 119/438 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MAST4 | c.2289G>A p.P763= (on ENST00000403625 / NM_001164664.2; = p.P574= on NM_015183.3) | Silent (SNP) | VAF 111/447 reads (25%) | catalogued as rs369291811; called by muse, mutect2, varscan2
- CPNE4 | chr3:132037564 C>A | 5'Flank (SNP) | VAF 76/372 reads (20%) | called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins TTTCGA | 3'Flank (INS) | VAF 52/218 reads (24%) | called by mutect2, pindel, varscan2
